Somatic mutation profile of tumor specimen ALCH-AE2O-TTP1-A (aliquot ALCH-AE2O-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-AE2O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.8 years (27,684 days).
Specimen ALCH-AE2O-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ceaab79-ac3f-4842-8f70-e8543942cb31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE2O-NB1-A (Blood Derived Normal), aliquot ALCH-AE2O-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b00c0a-7037-4297-b270-682c3853b9c3

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Intron 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB2 | c.3523C>T p.L1175F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV63501595; called by muse, mutect2
- KALRN | c.6310A>G p.M2104V (on ENST00000360013 / NM_001024660.4; = p.M407V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/647 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.399); catalogued as rs1485404830; called by muse, mutect2
- MYO19 | c.1553A>G p.H518R | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs773208403; called by muse, mutect2
- NARS1 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900566; called by muse, mutect2
- RIMS4 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 50/938 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1272618279, COSV65720973; called by muse, mutect2
- ATP1A2 | c.1047G>C p.M349I | Missense Mutation (SNP) | VAF 147/1076 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CASQ2 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 65/990 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR20 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- GRIA4 | c.2467G>T p.G823C | Missense Mutation (SNP) | VAF 50/1052 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HIVEP2 | c.1348A>G p.M450V | Missense Mutation (SNP) | VAF 36/736 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- KRT33B | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- LRP1 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 58/1238 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- OBSCN | c.7832G>T p.R2611L | Missense Mutation (SNP) | VAF 120/926 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PTPA | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 36/591 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.007); called by muse, mutect2
- SDF2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 42/626 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2
- SFSWAP | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 36/559 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- TCEAL9 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 18/413 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TNPO3 | c.572C>A p.A191E | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2
- TTN | c.19501A>G p.I6501V (on ENST00000591111; = p.I5574V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.5588A>G p.E1863G | Missense Mutation (SNP) | VAF 38/569 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2
- CCDC186 | c.279A>T p.I93= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- DNAH7 | c.5292G>A p.L1764= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- DTHD1 | c.414A>G p.T138= (on ENST00000456874; = p.T263= on NM_001170700.3) | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1467171327; called by muse, mutect2
- MLXIP | c.147G>A p.P49= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs1275911785; called by muse, mutect2, varscan2
- PXDNL | c.2295C>A p.R765= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100681376; called by muse, mutect2, varscan2
- TNRC6C | c.2949C>T p.D983= | Silent (SNP) | VAF 38/641 reads (6%) | called by muse, mutect2
- ZNF358 | c.1359C>T p.S453= | Silent (SNP) | VAF 33/362 reads (9%) | catalogued as rs763706118; called by muse, mutect2
- ZNF423 | c.1377C>T p.P459= (on ENST00000563137 / NM_001379286.1; = p.P451= on NM_015069.4) | Silent (SNP) | VAF 58/756 reads (8%) | catalogued as rs770488069; called by muse, mutect2
- CHRNA10 | c.-48G>A | 5'UTR (SNP) | VAF 55/583 reads (9%) | called by muse, mutect2
- NDUFA6 | c.-4C>A | 5'UTR (SNP) | VAF 58/740 reads (8%) | called by muse, mutect2
- ROBO1 | c.1046-4572A>C | Intron (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- STX1A | c.678+75G>T | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
